PECGS case C083-000018 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/b54b31c5-665e-46ae-b43c-39c9486ca6f8

Demographics
Sex at birth: female; Race: white; Age at index: 62 years; Year of birth: 1956; Education level: College Degree.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; Age at diagnosis: 61.7 years (22,536 days); AJCC pathologic stage: Stage IIA; Progression or recurrence: no.
2. Sebaceous adenocarcinoma: ICD-O-3 morphology code: 8410/3; Age at diagnosis: 61.7 years (22,536 days); AJCC pathologic stage: Stage IA; Progression or recurrence: no.

Other clinical attributes
- BMI: 21.03; Menopause status: Postmenopausal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Alcohol history: Yes.

Biospecimens (2 samples)
- Sample C083-000018_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000018_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
